MMRF case MMRF_1355 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/49d4af66-7850-4687-bdc2-27b4d862d180

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.0 years (27,387 days); ISS stage: I; Days to last known disease status: 1,464 days (4.0 years); Days to last follow up: 1,464 days (4.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 1,282 days (3.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 9.5 g/L; Immunoglobulin A 21 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 2.4 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.29 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.05 mmol/L; Albumin 37 g/L; Total Protein 8.1 g/dL; Glucose 4.95 mmol/L.
- Day 113 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 8.18 g/L; Immunoglobulin A 4.65 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.36 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 169 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.57 mg/dL; Immunoglobulin G 9.82 g/L; Immunoglobulin A 5.77 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 6.38 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.49 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Immunoglobulin G 7.15 g/L; Immunoglobulin A 3.7 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.88 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 5.34 mmol/L.
- Day 337 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.53 mg/dL; Immunoglobulin G 8.34 g/L; Immunoglobulin A 5.69 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 8.14 mmol/L.
- Day 436 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.02 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 7.66 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.07 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 7.4 g/dL; Glucose 6.82 mmol/L.
- Day 533 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.93 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 7.84 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.06 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 6.8 g/dL; Glucose 6.22 mmol/L.
- Day 615 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.83 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 9.5 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.27 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 7.5 g/dL; Glucose 7.65 mmol/L.
- Day 708 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.07 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 9.79 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.7 g/dL; Glucose 7.65 mmol/L.
- Day 799 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.64 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 8.4 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 0.82 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 911 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.86 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 5.27 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.18 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 5.67 mmol/L.
- Day 967 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.62 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 6.72 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.05 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 4.79 mmol/L.
- Day 1,058 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.05 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 6.86 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 7.4 g/dL; Glucose 5.28 mmol/L.
- Day 1,170 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 5.1 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.32 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.05 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 5.06 mmol/L.
- Day 1,282 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.84 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 5.05 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 5.07 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 1,364 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.37 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 4.71 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.65 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 5.94 mmol/L.
- Day 1,464 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.34 mg/dL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day -13: Weight: 79 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (5 samples)
- Sample MMRF_1355_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1355_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
- Sample MMRF_1355_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 260 days.
- Sample MMRF_1355_4_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 260 days.
- Sample MMRF_1355_5_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 533 days (1.5 years).
